TCGA case TCGA-W3-A825 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Bronchus and lung; Tissue source site: John Wayne Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f5d8110-35c7-419f-8b35-bc3040f940f3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 1,917 days (5.2 years).

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C34.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lower lobe, lung; Classification of tumor: metastasis; Age at diagnosis: 65.0 years (23,741 days); Days to diagnosis: 1,644 days (4.5 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.5 years (22,097 days); Year of diagnosis: 1998; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Dacarbazine + Tamoxifen + Vinblastine; Days to treatment start: 1,644 days (4.5 years); Days to treatment end: 1,767 days (4.8 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Recombinant Interferon Alfa + Recombinant Interleukin-2; Days to treatment start: 1,644 days (4.5 years); Days to treatment end: 1,767 days (4.8 years); Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,917 days (5.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 162 cm; BMI: 29.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W3-A825-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-W3-A825-06A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-W3-A825-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W3-A825-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 1.3; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: Lung; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Drug treatment 5: Pharmaceutical therapy drug name: Interleukin-2.
- Drug treatment 6: Pharmaceutical therapy drug name: Interferon-α2.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,917 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,917 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,917 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W3-A825-06A-11D-A34T-01): tumor purity 0.69, ploidy 3.09, whole-genome doublings 1.
